Gene-level copy-number profile of tumor specimen TCGA-86-7711-01A from TCGA case TCGA-86-7711, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.4 years (25,719 days).
Specimen TCGA-86-7711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e6cde20d-d2be-46ba-b552-4c8bb18a979e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-7711-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be55ce5d-fe0c-42ef-9802-7d38d3aa68b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 21,435; copy number 2: 30,227; copy number 3: 4,293; copy number 4: 3,534; copy number 5: 183; copy number 6: 64; copy number 7: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-7711-01A-11D-2062-01): tumor purity 0.33, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:57,261,354–57,359,898, 9 genes: AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 314 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,523,962, 55 genes, copy number 5 (within-gene range 4–5): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1.
- chr5:6,839,460–7,219,291, 1 gene, copy number 6 (within-gene range 4–6): LINC02196.
- chr5:7,047,227–7,830,081, 15 genes, copy number 6 (within-gene range 4–6): RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1.
- chr5:8,980,404–10,082,772, 20 genes, copy number 5: AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4.
- chr5:22,580,225–32,791,724, 123 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:35,617,844–41,587,787, 100 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,021. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
